Surgical pathology report (de-identified scan), TCGA case TCGA-5P-A9K3, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site University Hospital Erlangen, specimen TCGA-5P-A9K3-01A (Primary Tumor).

ICD O3
Carcinoma, papillary renal
cell 8260/3
Site: (R) Kidney NOS C64.9
6/13/14

Papillary Renal Cell Carcinoma, Type II, poorly differentiated

Stage: pT2, pNX, pMX, R0

Grade: GIII

ICD-O-Code: 8260/3

Laterality = (R)

Source: NCI Genomic Data Commons file 6d48e211-dae3-4bf9-a799-05f517cb4ed6 (TCGA-5P-A9K3.053C8A91-4C61-4DCB-B24B-CC50E556EF9A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).